CCDI case PBBXAZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/0be1d02b-f75f-44e3-9cb9-5d8108ba4962

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.2 years (4,463 days).

Biospecimens (3 samples)
- Sample 0DJIKV: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DJIL6, 0DJIM3 (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
